Somatic mutation profile of tumor specimen TCGA-FZ-5920-01A (aliquot TCGA-FZ-5920-01A-11D-1609-08) from TCGA case TCGA-FZ-5920, project TCGA-PAAD (Pancreatic Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Head of pancreas; AJCC pathologic stage: Stage IIB; Tumor grade: G3; Age at diagnosis: 52.8 years (19,287 days).
Specimen TCGA-FZ-5920-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d1ce567d-67aa-4db0-8efd-7d5a84177f60.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FZ-5920-11A (Solid Tissue Normal), aliquot TCGA-FZ-5920-11A-01D-1609-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3ed7c948-ca2d-4bd2-996e-6663fc613069

The open-access MAF lists 60 somatic variants for this specimen: 45 protein-altering or splice-affecting, 14 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 37, Silent 14, Nonsense Mutation 3, Frame Shift Del 3, Frame Shift Ins 1, Intron 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 58/186 reads (31%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.454_466del p.P152Afs*14 | Frame Shift Del (DEL) | VAF 55/375 reads (15%) | catalogued as rs876659215; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- ACHE | c.712G>A p.A238T | Missense Mutation (SNP) | VAF 41/489 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as rs759058537, COSV99574673; called by muse, mutect2
- ADGRG5 | c.899T>C p.L300P | Missense Mutation (SNP) | VAF 22/255 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.975); catalogued as COSV100446540; called by muse, mutect2
- APBA1 | c.1027C>T p.R343C | Missense Mutation (SNP) | VAF 26/480 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs761546408, COSV55221217; called by muse, mutect2
- APBA2 | c.2023G>A p.V675M | Missense Mutation (SNP) | VAF 125/616 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs751602124, COSV68788501; called by muse, mutect2, varscan2
- BIN2 | c.983C>A p.A328E | Missense Mutation (SNP) | VAF 35/494 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0.368); catalogued as COSV99909802; called by muse, mutect2
- CAMK4 | c.1099G>A p.E367K | Missense Mutation (SNP) | VAF 44/532 reads (8%) | SIFT tolerated (0.14); PolyPhen benign (0.019); catalogued as rs772366765, COSV100000508; called by muse, mutect2
- CDKN2A | c.148del p.Q50Rfs*3 | Frame Shift Del (DEL) | VAF 270/1363 reads (20%) | catalogued as CM023895, COSV58683786; called by pindel, varscan2
- CHL1 | c.2859T>A p.Y953* (on ENST00000397491 / NM_001253387.1; = p.Y969* on NM_006614.4) | Nonsense Mutation (SNP) | VAF 31/412 reads (8%) | catalogued as COSV99851050, COSV99852679; called by muse, mutect2
- COL25A1 | c.1150A>G p.K384E | Missense Mutation (SNP) | VAF 27/223 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as COSV67648525, COSV67654922; called by muse, mutect2, varscan2
- CRB2 | c.140G>A p.C47Y | Missense Mutation (SNP) | VAF 95/834 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.498); catalogued as rs746496927, COSV100749765; called by muse, mutect2, varscan2
- DNAH7 | c.6752G>A p.R2251H | Missense Mutation (SNP) | VAF 172/788 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs778541588, COSV56771368; called by muse, mutect2, varscan2
- FANCC | c.1652T>C p.L551P | Missense Mutation (SNP) | VAF 18/215 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100003234; called by muse, mutect2
- FASTK | c.560G>A p.R187H | Missense Mutation (SNP) | VAF 21/81 reads (26%) | SIFT tolerated (0.13); PolyPhen benign (0.375); catalogued as rs761778464, COSV99880034; called by muse, mutect2
- FBXO16 | c.343G>A p.V115M | Missense Mutation (SNP) | VAF 22/298 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1216851836, COSV100672516; called by muse, mutect2
- HOXC11 | c.328G>A p.V110I | Missense Mutation (SNP) | VAF 348/1683 reads (21%) | SIFT tolerated (0.45); PolyPhen benign (0.104); catalogued as rs778637728, COSV99678573; called by muse, mutect2, varscan2
- HSPA8 | c.218T>C p.L73P | Missense Mutation (SNP) | VAF 89/424 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV99914690; called by muse, mutect2, varscan2
- IL27 | c.134G>A p.R45K | Missense Mutation (SNP) | VAF 88/408 reads (22%) | SIFT tolerated (0.28); PolyPhen benign (0.005); catalogued as rs1226561650, COSV100795925; called by muse, mutect2, varscan2
- KIFC3 | c.221G>A p.R74Q | Missense Mutation (SNP) | VAF 29/232 reads (13%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0); catalogued as rs782261569, COSV65553579; called by muse, mutect2, varscan2
- KSR2 | c.1087C>T p.R363C | Missense Mutation (SNP) | VAF 26/99 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.551); catalogued as rs375751976, COSV56671133; called by muse, mutect2, varscan2
- MAPK10 | c.1138G>T p.A380S (on ENST00000359221 / NM_001351625.2; = p.A418S on NM_002753.5) | Missense Mutation (SNP) | VAF 24/422 reads (6%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.001); catalogued as COSV100175693; called by muse, mutect2
- METTL27 | c.536C>G p.A179G | Missense Mutation (SNP) | VAF 68/357 reads (19%) | SIFT tolerated (0.2); PolyPhen benign (0.276); catalogued as COSV99936646; called by muse, mutect2, varscan2
- MTMR12 | c.548T>A p.L183Q | Missense Mutation (SNP) | VAF 96/514 reads (19%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.972); catalogued as COSV99374190; called by muse, mutect2, varscan2
- NLGN3 | c.1838G>A p.R613Q (on ENST00000358741 / NM_181303.2; = p.R593Q on NM_018977.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.919); catalogued as COSV62441987; called by muse, mutect2, varscan2
- NPAP1 | c.3050G>A p.G1017D | Missense Mutation (SNP) | VAF 32/350 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.917); catalogued as COSV61504384; called by muse, mutect2
- OR8H2 | c.670A>G p.T224A | Missense Mutation (SNP) | VAF 76/844 reads (9%) | SIFT tolerated (0.31); PolyPhen benign (0.12); catalogued as COSV100542529; called by muse, mutect2
- QRICH2 | c.1618G>T p.D540Y | Missense Mutation (SNP) | VAF 43/393 reads (11%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as COSV99429847; called by muse, mutect2, varscan2
- RANBP9 | c.1027C>T p.R343W | Missense Mutation (SNP) | VAF 88/706 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1029630802, COSV99163648; called by muse, varscan2
- RBM5 | c.598A>G p.K200E | Missense Mutation (SNP) | VAF 65/289 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as COSV100762544; called by muse, mutect2, varscan2
- RYR1 | c.3299G>A p.R1100H | Missense Mutation (SNP) | VAF 57/745 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs755973279, COSV62110112; ClinVar: uncertain significance; called by muse, mutect2
- SAMD7 | c.53T>C p.I18T | Missense Mutation (SNP) | VAF 69/773 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.058); catalogued as COSV100157127; called by muse, mutect2
- SPATA20 | c.2008G>A p.V670M (on ENST00000356488 / NM_001258372.1; = p.V686M on NM_022827.4) | Missense Mutation (SNP) | VAF 76/616 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.308); catalogued as rs1373386477, COSV99136898; called by muse, mutect2, varscan2
- SRMS | c.1034G>A p.R345H | Missense Mutation (SNP) | VAF 13/86 reads (15%) | SIFT tolerated (0.55); PolyPhen benign (0.001); catalogued as rs751206072, COSV99420932; called by muse, mutect2, varscan2
- STXBP5 | c.124C>T p.Q42* | Nonsense Mutation (SNP) | VAF 19/202 reads (9%) | catalogued as COSV99471175; called by muse, mutect2
- SZT2 | c.2251A>G p.I751V | Missense Mutation (SNP) | VAF 23/159 reads (14%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.552); catalogued as COSV100987726; called by muse, mutect2, varscan2
- TBX20 | c.860G>A p.R287Q | Missense Mutation (SNP) | VAF 32/350 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1288985415, COSV101282407, COSV68784194; called by muse, mutect2
- ZEB2 | c.1835C>T p.A612V | Missense Mutation (SNP) | VAF 54/569 reads (9%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.995); catalogued as rs1206446041, COSV57958275; called by muse, mutect2
- ZNF202 | c.994G>C p.D332H | Missense Mutation (SNP) | VAF 189/1812 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV100279190; called by muse, mutect2, varscan2
- ZNF700 | c.1127C>G p.S376* | Nonsense Mutation (SNP) | VAF 110/445 reads (25%) | catalogued as COSV99583884; called by muse, mutect2, varscan2
- ZNF799 | c.776C>A p.S259Y | Missense Mutation (SNP) | VAF 76/864 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.551); catalogued as COSV101345305; called by muse, mutect2
- ZRANB3 | c.908C>T p.A303V | Missense Mutation (SNP) | VAF 92/883 reads (10%) | SIFT tolerated (0.38); PolyPhen benign (0.077); catalogued as COSV99925097; called by muse, mutect2, varscan2
- AP5B1 | c.1608_1618del p.L537Pfs*67 | Frame Shift Del (DEL) | VAF 14/151 reads (9%) | called by mutect2, pindel
- DNAH2 | c.9130_9132dup p.E3044dup | In Frame Ins (INS) | VAF 54/264 reads (20%) | called by mutect2, pindel, varscan2
- HEATR5B | c.3332dup p.N1111Kfs*9 | Frame Shift Ins (INS) | VAF 54/549 reads (10%) | called by mutect2, pindel
- AMPH | c.1482G>A p.A494= | Silent (SNP) | VAF 102/1150 reads (9%) | catalogued as rs756707743, COSV100341904, COSV57733795; ClinVar: likely benign; called by muse, mutect2
- CDH22 | c.1239C>A p.V413= | Silent (SNP) | VAF 6/40 reads (15%) | catalogued as COSV100953004, COSV64836522; called by muse, mutect2
- CYP4F11 | c.1521C>T p.R507= | Silent (SNP) | VAF 25/257 reads (10%) | catalogued as rs774161991, COSV56126883, COSV99931035; called by muse, mutect2
- DLC1 | c.2058G>A p.A686= (on ENST00000276297 / NM_001348081.2; = p.A249= on NM_006094.5) | Silent (SNP) | VAF 77/750 reads (10%) | catalogued as rs372344109; called by muse, mutect2, varscan2
- DST | c.19506T>A p.L6502= (on ENST00000361203 / NM_001374722.1; = p.L4199= on NM_015548.5) | Silent (SNP) | VAF 18/130 reads (14%) | catalogued as COSV99760894; called by muse, mutect2, varscan2
- H4C2 | c.198G>A p.V66= | Silent (SNP) | VAF 47/332 reads (14%) | catalogued as rs192365376, COSV55140871, COSV99774872, COSV99775131; called by muse, mutect2, varscan2
- HAND2 | c.198C>T p.P66= | Silent (SNP) | VAF 9/83 reads (11%) | catalogued as COSV100854143, COSV64018926; called by muse, mutect2
- HHIPL2 | c.882G>A p.S294= | Silent (SNP) | VAF 400/2048 reads (20%) | catalogued as rs182148496, COSV58563604, COSV58564483; called by muse, mutect2, varscan2
- KRTAP26-1 | c.99C>T p.S33= | Silent (SNP) | VAF 69/491 reads (14%) | catalogued as rs897810268, COSV100860519, COSV100860521; called by muse, mutect2, varscan2
- LAP3 | c.39C>G p.V13= | Silent (SNP) | VAF 7/56 reads (13%) | catalogued as COSV99884716; called by muse, mutect2
- TMEM130 | c.636G>A p.A212= | Silent (SNP) | VAF 24/212 reads (11%) | catalogued as rs917628738, COSV100229072; called by muse, mutect2, varscan2
- ZBED9 | c.3774T>C p.P1258= | Silent (SNP) | VAF 14/406 reads (3%) | catalogued as rs1445235216, COSV101509424; called by muse, mutect2
- ZEB2 | c.3207G>A p.S1069= | Silent (SNP) | VAF 58/518 reads (11%) | catalogued as COSV57951038, COSV57956275; called by muse, mutect2, varscan2
- ZNF536 | c.1029C>T p.N343= | Silent (SNP) | VAF 132/1341 reads (10%) | catalogued as rs760335471, COSV62827992; called by muse, mutect2, varscan2
- TTN | c.10360+3487G>T | Intron (SNP) | VAF 59/525 reads (11%) | catalogued as COSV59911084; called by muse, mutect2, varscan2
